Somatic mutation profile of tumor specimen TCGA-VQ-A925-01A (aliquot TCGA-VQ-A925-01A-11D-A410-08) from TCGA case TCGA-VQ-A925, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 66.3 years (24,230 days).
Specimen TCGA-VQ-A925-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36b8a8e1-bb82-4a01-9d5c-21bc769f7d40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A925-10A (Blood Derived Normal), aliquot TCGA-VQ-A925-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afad664b-479c-4c12-a35d-2d01824a6906

The open-access MAF lists 130 somatic variants for this specimen: 95 protein-altering or splice-affecting, 31 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 31, Frame Shift Del 3, RNA 3, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.738G>A p.M246I | Missense Mutation (SNP) | VAF 21/67 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1019340046, COSV52735934, COSV52772732, COSV53038458, COSV53481758; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.2983A>G p.I995V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs374500043; called by muse, mutect2, varscan2
- ABCG2 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.913); catalogued as COSV99419862; called by muse, mutect2, varscan2
- AC131160.1 | c.84G>C p.E28D | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV100226337; called by muse, mutect2, varscan2
- ACER2 | c.661del p.A221Lfs*85 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as COSV61821308; called by mutect2, pindel, varscan2
- ADAMTS17 | c.1441G>C p.G481R | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99171420; called by muse, mutect2, varscan2
- ADGRB1 | c.4442A>T p.D1481V | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100030143; called by muse, mutect2, varscan2
- ADGRF4 | c.1291G>T p.V431F | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99348817; called by muse, mutect2, varscan2
- ADGRL4 | c.813T>A p.H271Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.98); PolyPhen benign (0.011); catalogued as COSV100876394; called by muse, varscan2
- ADGRL4 | c.299T>C p.I100T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.018); catalogued as COSV100876395; called by muse, varscan2
- ADGRV1 | c.3362T>G p.F1121C | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101316314; called by muse, mutect2, varscan2
- AOX1 | c.589-1G>A p.X197_splice | Splice Site (SNP) | VAF 13/45 reads (29%) | catalogued as COSV101022182; called by muse, mutect2, varscan2
- APOBR | c.1573G>C p.G525R (on ENST00000431282; = p.G534R on NM_018690.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.112); catalogued as COSV100112365, COSV100112773; called by muse, mutect2, varscan2
- C10orf71 | c.1355C>G p.P452R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV100110514; called by muse, mutect2, varscan2
- CCN6 | c.937A>G p.I313V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.416); catalogued as COSV100037154; called by muse, mutect2, varscan2
- CDH11 | c.1580T>G p.F527C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV51750134; called by muse, mutect2, varscan2
- CFAP44 | c.2839C>T p.R947W | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs141547615; called by muse, mutect2, varscan2
- CFAP47 | c.1174A>C p.S392R | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.594); catalogued as COSV52886455, COSV52894132; called by muse, mutect2, varscan2
- CMTR2 | c.796C>G p.L266V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766157732, COSV100579295; called by muse, mutect2, varscan2
- CNTN4 | c.2758A>G p.N920D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV100639541; called by muse, mutect2, varscan2
- CNTNAP2 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV62140241, COSV62213628; called by muse, mutect2, varscan2
- COL22A1 | c.4073T>C p.L1358P | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV100279936; called by muse, mutect2, varscan2
- CSMD1 | c.8830C>T p.R2944C (on ENST00000520002; = p.R2943C on NM_033225.6) | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1431976322, COSV59318142; called by muse, mutect2, varscan2
- DAPK2 | c.102T>G p.F34L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99977647; called by muse, mutect2, varscan2
- DPYD | c.1756G>A p.V586I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV100928908, COSV100929261; called by muse, mutect2, varscan2
- DYNC2H1 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs374104623; called by muse, mutect2, varscan2
- FADS3 | c.272T>G p.L91R | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1385580991, COSV99605444; called by muse, mutect2, varscan2
- FGL1 | c.721C>A p.H241N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101112498; called by muse, mutect2, varscan2
- FSCB | c.1205A>T p.E402V | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV100469682; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.79); PolyPhen benign (0.102); catalogued as rs781911392, COSV63100456; called by muse, mutect2, varscan2
- GZMA | c.85dup p.I29Nfs*6 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | catalogued as rs749101759; called by mutect2, pindel, varscan2
- H2BC5 | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99175214, COSV99175335; called by muse, mutect2, varscan2
- HHAT | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs367896407; called by muse, mutect2, varscan2
- HTR2C | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs782400565, COSV99350454; called by muse, mutect2
- IGSF10 | c.3478G>A p.A1160T | Missense Mutation (SNP) | VAF 114/228 reads (50%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs553213263, COSV56781590; called by muse, mutect2, varscan2
- INTS13 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.171); catalogued as COSV99677537; called by muse, mutect2, varscan2
- KCNU1 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV101299393; called by muse, mutect2, varscan2
- KDM4C | c.1884del p.F628Lfs*14 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as COSV67194704; called by mutect2, pindel, varscan2
- KIF20B | c.1348A>G p.I450V | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0.212); catalogued as COSV99590535; called by muse, mutect2, varscan2
- KIF26B | c.4894G>A p.A1632T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs866622290, COSV63645426; called by muse, mutect2
- KIR3DL2 | c.317G>A p.W106* | Nonsense Mutation (SNP) | VAF 73/120 reads (61%) | catalogued as COSV99551957, COSV99552370; called by muse, mutect2, varscan2
- KLHL1 | c.2083G>T p.V695F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs373985895; called by muse, mutect2, varscan2
- LRP1 | c.5002G>A p.V1668I | Missense Mutation (SNP) | VAF 89/126 reads (71%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99676761; called by muse, mutect2, varscan2
- LRP1B | c.9129C>A p.N3043K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV101259276, COSV67241189; called by muse, mutect2
- LRRC8D | c.1472A>T p.D491V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV100487469; called by muse, mutect2, varscan2
- MEIS2 | c.943G>C p.D315H (on ENST00000561208 / NM_170675.5; = p.D302H on NM_002399.3) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99576994; called by muse, mutect2, varscan2
- MLLT10 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as COSV100308574; called by muse, mutect2, varscan2
- MOXD1 | c.972G>T p.R324S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs373260587; called by muse, mutect2
- MPDZ | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as COSV100064030; called by muse, mutect2, varscan2
- MUC16 | c.13729G>A p.A4577T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs372775227; called by muse, mutect2, varscan2
- MYO1F | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs371339136; called by muse, mutect2, varscan2
- NOVA1 | c.1355G>T p.G452V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99948390; called by muse, mutect2, varscan2
- NUBP1 | c.599C>G p.T200S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV99296912; called by muse, mutect2, varscan2
- OTULIN | c.604T>A p.L202M | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.864); catalogued as COSV99419953; called by muse, mutect2, varscan2
- OXSM | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99772093; called by muse, mutect2, varscan2
- PCDHB11 | c.2137C>A p.L713M | Missense Mutation (SNP) | VAF 84/147 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100697128; called by muse, mutect2, varscan2
- PCDHB15 | c.2304G>T p.K768N | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.062); catalogued as COSV99179103; called by muse, mutect2, varscan2
- PDE2A | c.1646C>A p.A549D | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.676); catalogued as rs1424871982, COSV100558279; called by muse, mutect2, varscan2
- PIK3CD | c.1715C>A p.P572Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100740388, COSV100740473; called by muse, mutect2, varscan2
- PIK3R4 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777072326, COSV100768546, COSV63242192; called by muse, mutect2, varscan2
- PNPLA7 | c.910G>C p.V304L | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.065); catalogued as COSV99481208; called by muse, mutect2
- PRDM9 | c.458C>A p.S153Y | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.259); catalogued as COSV99690951; called by muse, mutect2, varscan2
- PRRX1 | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1272026144, COSV53410909, COSV99509643; called by muse, mutect2
- PZP | c.2138T>G p.V713G | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99738945; called by muse, mutect2, varscan2
- RFTN2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs1387590158, COSV54387374, COSV99695889; called by muse, mutect2, varscan2
- RTF1 | c.1243T>C p.Y415H | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101048109; called by muse, mutect2, varscan2
- SCAP | c.3368C>T p.T1123M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770001989, COSV99650895; called by muse, mutect2, varscan2
- SCN5A | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as rs199473577, CM100661, COSV100349935; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN9A | c.3229C>T p.Q1077* (on ENST00000303354; = p.Q1066* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as rs1553486633, COSV100312032, COSV100313722; called by muse, mutect2, varscan2
- SDK1 | c.6523G>A p.G2175S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV101269677; called by muse, mutect2, varscan2
- SLC22A16 | c.1276G>T p.A426S | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.191); catalogued as COSV100397772; called by muse, mutect2, varscan2
- SLC4A5 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs374602113; called by muse, mutect2, varscan2
- SPSB2 | c.480G>C p.Q160H | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs12370300; called by muse, mutect2, varscan2
- SPTA1 | c.5944C>G p.Q1982E | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV100935360; called by muse, mutect2, varscan2
- SPTA1 | c.1989T>G p.S663R | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV100935362; called by muse, mutect2, varscan2
- STK11 | c.783C>G p.Y261* | Nonsense Mutation (SNP) | VAF 14/21 reads (67%) | catalogued as CM147057, COSV100480835; called by muse, mutect2, varscan2
- TM4SF4 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100541951, COSV59515403; called by muse, mutect2
- TMEM182 | c.75T>A p.F25L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as COSV101305407; called by muse, mutect2, varscan2
- TMLHE | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV100545033; called by muse, mutect2, varscan2
- TNRC6C | c.1045C>G p.Q349E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100050489; called by muse, mutect2, varscan2
- TRHDE | c.2813A>C p.K938T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV53849652, COSV99671921; called by muse, mutect2, varscan2
- TRIM49 | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV61670608; called by muse, mutect2, varscan2
- USP25 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs913192559, COSV99584341; called by muse, mutect2, varscan2
- UVRAG | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 72/279 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.807); catalogued as COSV100638543; called by muse, mutect2, varscan2
- VPS39 | c.2206G>C p.D736H (on ENST00000348544 / NM_001301138.2; = p.D725H on NM_015289.5) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV100529441, COSV58788832; called by muse, mutect2, varscan2
- VPS51 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as rs765877173, COSV54207481, COSV54209318; called by muse, mutect2, varscan2
- XIRP2 | c.3851A>G p.H1284R (on ENST00000628543; = p.H1459R on NM_152381.6) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV99746071; called by muse, mutect2, varscan2
- ZFHX4 | c.1819G>A p.G607S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.336); catalogued as rs770173843, COSV99266149; called by muse, mutect2, varscan2
- ZKSCAN8 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.788); catalogued as rs777066140, COSV57636806; called by muse, mutect2, varscan2
- ZNF287 | c.1588C>G p.H530D | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101209403; called by muse, mutect2, varscan2
- ZNF607 | c.836A>C p.K279T | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100777938; called by muse, mutect2, varscan2
- ZZZ3 | c.1786G>C p.D596H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100890407; called by muse, mutect2, varscan2
- F5 | c.225_231del p.K75Nfs*22 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | called by mutect2, pindel, varscan2
- PTPN13 | c.3045G>T p.L1015F | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.157); called by muse, mutect2
- TP53 | c.667_672+1dup p.X223_splice | Splice Site (INS) | VAF 12/20 reads (60%) | called by mutect2, varscan2
- CALCA | c.147C>T p.L49= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100524080; called by muse, mutect2, varscan2
- CCR3 | c.993T>A p.L331= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100656690; called by muse, mutect2, varscan2
- CORO1A | c.1104A>G p.A368= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as rs1472585091, COSV99532148; called by muse, mutect2, varscan2
- CSMD1 | c.9882T>G p.T3294= (on ENST00000520002; = p.T3293= on NM_033225.6) | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100152216; called by muse, mutect2, varscan2
- CUL7 | c.2667G>A p.L889= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99539094; called by muse, mutect2
- DCDC2B | c.612G>A p.E204= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99356753; called by muse, mutect2, varscan2
- DNAH1 | c.10683G>A p.P3561= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs372328204; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAJC12 | c.459G>A p.K153= | Silent (SNP) | VAF 18/278 reads (6%) | catalogued as COSV56548367, COSV99830710; called by muse, mutect2
- EIF4G3 | c.162G>A p.L54= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV99945177; called by muse, mutect2, varscan2
- EPPK1 | c.1254C>G p.A418= | Silent (SNP) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- FAT3 | c.1968T>C p.T656= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV99969029; called by muse, mutect2, varscan2
- HEPACAM | c.264C>T p.I88= | Silent (SNP) | VAF 46/142 reads (32%) | catalogued as rs368573598; called by muse, mutect2, varscan2
- HMGCS2 | c.943C>T p.L315= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV101024882; called by muse, mutect2, varscan2
- HRNR | c.2241T>A p.G747= | Silent (SNP) | VAF 20/217 reads (9%) | catalogued as rs771953292, COSV100913799; called by muse, mutect2
- IGSF22 | c.1575G>A p.A525= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs753621035, COSV100080201; called by muse, mutect2
- KCTD21 | c.303G>T p.V101= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100399777; called by muse, mutect2, varscan2
- MYO18B | c.6489G>C p.G2163= | Silent (SNP) | VAF 39/139 reads (28%) | catalogued as COSV100123670; called by muse, mutect2, varscan2
- OMP | c.240C>T p.I80= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV99582427; called by muse, mutect2, varscan2
- PCDH11Y | c.2988A>G p.Q996= (on ENST00000400457 / NM_032973.2; = p.Q985= on NM_032971.3) | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as COSV99292334; called by muse, mutect2, varscan2
- PITPNM3 | c.2748C>T p.F916= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV99338838; called by muse, mutect2, varscan2
- PRG3 | c.360T>C p.T120= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV99756050; called by muse, mutect2, varscan2
- PTPRM | c.1710T>C p.G570= | Silent (SNP) | VAF 40/62 reads (65%) | catalogued as COSV100159375; called by muse, mutect2, varscan2
- RYR3 | c.1119T>G p.T373= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV101212027, COSV101215037, COSV66780594; called by muse, mutect2, varscan2
- SCN8A | c.3045G>T p.V1015= | Silent (SNP) | VAF 28/39 reads (72%) | catalogued as COSV100634106; called by muse, mutect2, varscan2
- SEMA6D | c.2868T>G p.T956= (on ENST00000316364 / NM_153618.2; = p.T894= on NM_020858.2) | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV60372208; called by muse, mutect2, varscan2
- SLC24A3 | c.573C>T p.I191= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as rs1031769067, COSV100042487; called by muse, mutect2, varscan2
- SPATA25 | c.279C>T p.F93= | Silent (SNP) | VAF 64/167 reads (38%) | catalogued as COSV99510067; called by muse, mutect2, varscan2
- TRIM46 | c.1749C>T p.G583= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1241837433, COSV58112122; called by muse, mutect2
- TTN | c.64656A>C p.P21552= (on ENST00000591111; = p.P14128= on NM_003319.4) | Silent (SNP) | VAF 50/169 reads (30%) | catalogued as COSV100624037; called by muse, mutect2, varscan2
- ZFP37 | c.1515T>A p.T505= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100953305; called by muse, mutect2, varscan2
- ZFR | c.2559G>A p.L853= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV99416357; called by muse, mutect2, varscan2
- DCHS2 | n.5236A>C | RNA (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100601164, COSV61769884; called by muse, mutect2
- IGKV1-13 | n.4G>T | RNA (SNP) | VAF 13/71 reads (18%) | catalogued as rs1310448474; called by muse, varscan2
- MIR1269A | n.45A>G | RNA (SNP) | VAF 34/77 reads (44%) | catalogued as rs1560476511; called by muse, mutect2, varscan2
- PCDH15 | c.91+56215A>G | Intron (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100216218; called by muse, mutect2, varscan2
